TCGA case TCGA-D3-A8GN — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Small intestine; Tissue source site: MD Anderson. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7038de05-4e26-49af-b78a-5a00ce9a120b

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 27 years; Vital status: Alive.

Diagnoses (3)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C17.9; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Small intestine, NOS; Classification of tumor: metastasis; Age at diagnosis: 30.9 years (11,296 days); Days to diagnosis: 1,111 days (3.0 years); Prior treatment: Yes; Days to last follow up: 4,897 days (13.4 years).
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Interferon; Timepoint category: Prior to Procurement.
   Recorded as not given: Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 27.9 years (10,185 days); Year of diagnosis: 2000; AJCC staging edition: 7th; AJCC pathologic T: TX; AJCC pathologic N: N0; AJCC pathologic M: M0; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: Yes; Melanoma known primary: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Antineoplastic Vaccine; Days to treatment start: 1,224 days (3.4 years); Days to treatment end: 1,639 days (4.5 years); Treatment outcome: Complete Response; Clinical trial indicator: Yes.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
3. Metastasis of diagnosis 2 (Malignant melanoma, NOS), site: Lung, NOS. Age at diagnosis: 30.0 years (10,972 days); Days to diagnosis: 787 days (2.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 818 days (2.2 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (3 entries)
- Day 787 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 787 days (2.2 years).
- Days to follow up: 4,529 days (12.4 years); Disease response: Tumor Free.
- Days to follow up: 4,897 days (13.4 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 64 kg; Height: 165 cm; BMI: 23.5.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-D3-A8GN-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 180 mg.
  Slide TCGA-D3-A8GN-06A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-D3-A8GN-06Z: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-D3-A8GN-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: Yes; Tumor status: Tumor free; Primary location: Distant Metastasis; Metastatic tumor site: Duodenum; Prior radiation therapy: No; History neoadjuvant treatment: Yes; Ifn treatment 90 days prior to resection: Yes.
- Stage record: AJCC pathologic tumor stage: I/ii nos.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Subsequent known primaries: No.
- Drug treatment: Clinical trial drug classification: CancerVax.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 4,897 days; disease-specific survival: no event (censored), 4,897 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 787 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-D3-A8GN-06A-11D-A371-01): tumor purity 0.26, ploidy 3.68, whole-genome doublings 1.
